Somatic mutation profile of tumor specimen 97423edb-6f19-4b41-a7cb-af1635 (aliquot 97423edb-6f19-4b41-a7cb-af1635_D6_1) from CPTAC case 16CO006, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA.
Specimen 97423edb-6f19-4b41-a7cb-af1635: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aab00da6-d404-4717-8079-2b43f2991443.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c90a8f99-71b8-41bf-b60d-9be49c (Blood Derived Normal), aliquot c90a8f99-71b8-41bf-b60d-9be49c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc51a2bf-9f71-4b3d-91bd-01bd764bfa21

The open-access MAF lists 227 somatic variants for this specimen: 143 protein-altering or splice-affecting, 52 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 52, Nonsense Mutation 15, Intron 15, RNA 6, 5'UTR 5, Frame Shift Del 3, 3'UTR 3, Splice Site 2, 3'Flank 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 58/271 reads (21%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 52/224 reads (23%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 150/241 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PDE6B | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 138/526 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs201541131, CM155389; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 138/293 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACSM1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147062129; called by muse, mutect2, varscan2
- AGBL3 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV51951384; called by muse, mutect2, varscan2
- ARHGAP10 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.494); catalogued as COSV60601686; called by muse, mutect2, varscan2
- ARL6IP4 | c.800C>A p.S267Y (on ENST00000315580 / NM_018694.3; = p.S248Y on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs767437870; called by muse, mutect2, varscan2
- BHMT | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs755757711, COSV57155740; called by muse, mutect2, varscan2
- BLK | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs768186304; called by muse, mutect2, varscan2
- BSX | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 51/103 reads (50%) | catalogued as COSV58005607; called by muse, mutect2, varscan2
- CARD11 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 61/320 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as rs376539147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD93 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV55664721; called by muse, mutect2, varscan2
- CLRN2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs758709903, COSV71825283; called by muse, mutect2, varscan2
- DIS3L2 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs369229385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.1351C>G p.R451G | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65792429; called by muse, mutect2, varscan2
- EBF4 | c.1682G>A p.R561H (on ENST00000609451; = p.R557H on NM_001110514.1) | Missense Mutation (SNP) | VAF 128/287 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs751348568, COSV100712523, COSV61355663; called by muse, varscan2
- ERICH3 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs951721145, COSV100444840, COSV58606832; called by muse, mutect2, varscan2
- ESCO1 | c.1580A>G p.N527S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs1382151686, COSV52519271; called by muse, mutect2, varscan2
- FAT3 | c.5297C>G p.A1766G | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV53074356; called by muse, mutect2, varscan2
- FBXO40 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs141957650, COSV57525207; called by muse, mutect2, varscan2
- FHL5 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 42/88 reads (48%) | catalogued as rs140142641, COSV100459253; called by muse, mutect2, varscan2
- FN1 | c.6194C>T p.T2065M | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.564); catalogued as rs147481936, COSV60556963; called by muse, mutect2, varscan2
- GARNL3 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as rs1420761334; called by muse, mutect2, varscan2
- GDPD2 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 123/173 reads (71%) | catalogued as rs766368991, COSV65531859; called by muse, mutect2, varscan2
- H2BC12 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 150/341 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs774793061, COSV100804654; called by muse, mutect2, varscan2
- IL6 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 67/144 reads (47%) | catalogued as COSV51733644; called by muse, mutect2, varscan2
- ISLR2 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 120/472 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100679410; called by muse, mutect2, varscan2
- ITIH2 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs376208756; called by muse, mutect2, varscan2
- KDR | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 95/323 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1216864286, COSV55769199; called by muse, mutect2, varscan2
- LBP | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 186/338 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs545550026, COSV54141355; called by mutect2, varscan2
- LONP1 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs374217265, COSV62263334; called by muse, mutect2, varscan2
- MAG | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1304260702, COSV62700378; called by muse, mutect2, varscan2
- MCPH1 | c.1130C>G p.T377S | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100766143; called by muse, mutect2
- MEX3C | c.1035A>T p.K345N | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV68530149; called by muse, mutect2, varscan2
- MOV10L1 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 41/78 reads (53%) | catalogued as rs138868385; called by muse, mutect2, varscan2
- MYOM1 | c.2365_2367del p.N789del | In Frame Del (DEL) | VAF 13/68 reads (19%) | catalogued as rs1567925241; called by pindel, varscan2
- NFKB2 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 64/249 reads (26%) | catalogued as rs1337105771; called by muse, mutect2, varscan2
- NGRN | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 124/379 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.138); catalogued as rs144820175; called by muse, mutect2, varscan2
- NWD1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs868195008; called by muse, mutect2
- PCDHAC1 | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 86/419 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs782756674; called by muse, varscan2
- PHC2 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs377077362; called by muse, mutect2, varscan2
- PPIL2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs367840586; called by muse, mutect2, varscan2
- PRDM5 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99310307; called by muse, mutect2, varscan2
- RAG2 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs144812762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REG1A | c.365A>T p.K122M | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV52071166, COSV52071302; called by muse, mutect2, varscan2
- RP1 | c.4225G>T p.E1409* | Nonsense Mutation (SNP) | VAF 35/302 reads (12%) | catalogued as COSV55110138, COSV99609490; called by muse, mutect2, varscan2
- SALL1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1223836455, COSV51758197; called by muse, mutect2, varscan2
- SCN3A | c.4213G>C p.A1405P | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV51829722; called by muse, mutect2, varscan2
- SCN5A | c.2182G>A p.V728I | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs958480279, CM133678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETD2 | c.6325C>T p.R2109* | Nonsense Mutation (SNP) | VAF 10/167 reads (6%) | catalogued as COSV57430221; called by muse, mutect2
- SGIP1 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs566273210, COSV52767601; called by muse, mutect2, varscan2
- STIM2 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 80/308 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as rs764787780; called by muse, mutect2, varscan2
- TAF1L | c.3719G>A p.R1240Q | Missense Mutation (SNP) | VAF 103/417 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs539586559, COSV54259824; called by muse, mutect2, varscan2
- TCF7L2 | c.1268A>G p.Y423C (on ENST00000355995 / NM_001367943.1; = p.Y400C on NM_030756.5) | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53337091; called by muse, mutect2, varscan2
- TESK1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs763575051, COSV52412019; called by muse, mutect2
- TJAP1 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380777393, COSV99446302, COSV99446479; called by muse, mutect2, varscan2
- TNXB | c.12922G>A p.D4308N (on ENST00000647633; = p.D4061N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/1178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs569152212; called by muse, mutect2
- TUBA4B | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs532218261, COSV101203376; called by muse, mutect2, varscan2
- URB2 | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs760557526; called by muse, mutect2, varscan2
- VAV2 | c.1894C>T p.R632C (on ENST00000371850 / NM_001134398.2; = p.R622C on NM_003371.4) | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs749439328; called by muse, mutect2, varscan2
- VCAN | c.8801A>C p.N2934T | Missense Mutation (SNP) | VAF 74/285 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54096841; called by muse, mutect2, varscan2
- XPO5 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770376814; called by muse, mutect2, varscan2
- ZNF354A | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs913690436; called by muse, mutect2
- ZNF621 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs764224253; called by muse, mutect2, varscan2
- ZNF835 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.342); catalogued as rs576625581, COSV73379232; called by muse, mutect2
- AC138647.1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ANKRD17 | c.4768C>G p.P1590A | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); called by muse, mutect2
- ANKRD66 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- ANO5 | c.409T>G p.W137G | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- APBB1IP | c.907T>G p.F303V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRPF1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CACNA1B | c.745T>C p.F249L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA1D | c.4587+1G>A p.X1529_splice (on ENST00000350061 / NM_001128840.3; = p.X1549_splice on NM_000720.4) | Splice Site (SNP) | VAF 90/481 reads (19%) | called by muse, mutect2, varscan2
- CCDC80 | c.1968A>T p.K656N | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- CIDEA | c.452T>G p.M151R | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CIT | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- CLCA2 | c.2450A>C p.N817T | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CLDN10 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSPP1 | c.3407G>T p.R1136L (on ENST00000676605; = p.R1095L on NM_024790.6) | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CWC27 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX8 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- EBF1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 107/365 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EDDM3B | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EFCAB5 | c.1642A>G p.T548A | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAT4 | c.6844-1G>T p.X2282_splice | Splice Site (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- FAT4 | c.7708A>G p.R2570G | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FIZ1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 89/405 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOCAD | c.2057A>G p.N686S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GLYATL2 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- GRID2IP | c.2632A>T p.K878* | Nonsense Mutation (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- HENMT1 | c.121A>T p.N41Y | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- HRC | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- IL7R | c.672T>A p.Y224* | Nonsense Mutation (SNP) | VAF 53/453 reads (12%) | called by muse, mutect2, varscan2
- KCNC1 | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 50/524 reads (10%) | called by muse, mutect2
- KCNK2 | c.934C>T p.R312* (on ENST00000444842 / NM_001017425.3; = p.R297* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- KIAA1143 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- KRT1 | c.1180T>G p.S394A | Missense Mutation (SNP) | VAF 149/983 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by mutect2, varscan2
- LHCGR | c.1962del p.D655Ifs*24 | Frame Shift Del (DEL) | VAF 54/246 reads (22%) | called by mutect2, pindel, varscan2
- LRRC70 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LY9 | c.397del p.I133* | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | called by mutect2, varscan2
- MROH2B | c.182A>C p.K61T | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NOP2 | c.1225A>G p.T409A (on ENST00000322166 / NM_001258308.2; = p.T405A on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/213 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- NSMAF | c.1336A>C p.I446L | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- NUTM1 | c.1141A>T p.T381S | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPA3 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 37/446 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.099); called by muse, mutect2
- OR51A4 | c.171G>C p.L57F | Missense Mutation (SNP) | VAF 37/432 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- PARD6B | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 233/424 reads (55%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by mutect2, varscan2
- PATL2 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.09); called by mutect2, varscan2
- PCDHB10 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 131/630 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- PCDHB12 | c.719del p.P240Lfs*10 | Frame Shift Del (DEL) | VAF 79/429 reads (18%) | called by mutect2, pindel, varscan2
- PDE6C | c.527C>G p.T176S | Missense Mutation (SNP) | VAF 97/402 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PIEZO2 | c.4106G>A p.G1369E | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); called by muse, varscan2
- PLCL1 | c.1931C>A p.P644Q | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLK4 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLD1 | c.2545C>G p.R849G | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PPFIA3 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RCHY1 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- RGS12 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SAMD9L | c.2131A>C p.K711Q | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SLC16A6 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC22A1 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- SLC7A3 | c.670T>A p.Y224N | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SNX10 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SNX19 | c.839G>C p.S280T | Missense Mutation (SNP) | VAF 60/478 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by mutect2, varscan2
- SV2C | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- SYNPR | c.523A>C p.S175R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TANGO6 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- TLR6 | c.1572A>G p.I524M | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TNXB | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRGC2 | c.272G>T p.R91I | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TXNL1 | c.867C>G p.H289Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- UGCG | c.902T>C p.L301S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- UGT2B4 | c.620T>A p.F207Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UTS2B | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VPS54 | c.498dup p.M167Yfs*9 | Frame Shift Ins (INS) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- WNK1 | c.5165C>T p.A1722V (on ENST00000315939 / NM_018979.4; = p.A1475V on NM_014823.3) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF365 | c.870G>C p.E290D | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2
- ZNF444 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZNF69 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- ZNF805 | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 88/505 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); called by muse, varscan2
- ABCA4 | c.150C>T p.S50= | Silent (SNP) | VAF 30/266 reads (11%) | catalogued as rs777588686; called by muse, mutect2, varscan2
- CCDC150 | c.567G>A p.S189= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs146046280, COSV55873851, COSV55874197; called by muse, mutect2, varscan2
- CHST13 | c.186G>A p.P62= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs573241475, COSV60042955; called by muse, mutect2, varscan2
- CHST2 | c.1170C>T p.H390= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as rs1462976229, COSV58884919; called by muse, mutect2, varscan2
- COL4A5 | c.4050G>A p.P1350= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as rs368359594, COSV60369928; called by muse, mutect2, varscan2
- COMMD8 | c.279C>T p.C93= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs200625536; called by muse, mutect2, varscan2
- DCAF12L1 | c.288G>A p.T96= | Silent (SNP) | VAF 209/328 reads (64%) | catalogued as rs755461394, COSV64421925; called by muse, mutect2, varscan2
- DMRTC2 | c.432G>A p.P144= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs147524970; called by mutect2, varscan2
- EEF2K | c.921C>G p.L307= | Silent (SNP) | VAF 48/188 reads (26%) | catalogued as rs780243922; called by mutect2, varscan2
- FAM135B | c.3186C>A p.T1062= | Silent (SNP) | VAF 76/147 reads (52%) | catalogued as COSV52747819; called by muse, mutect2, varscan2
- FBN3 | c.2352C>T p.A784= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as rs200569494; called by muse, mutect2, varscan2
- FERD3L | c.441C>T p.I147= | Silent (SNP) | VAF 154/377 reads (41%) | catalogued as COSV51764094; called by muse, mutect2, varscan2
- FIBIN | c.477C>T p.N159= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as COSV100590464; called by muse, mutect2, varscan2
- FOCAD | c.3129C>T p.A1043= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as rs368218644; called by muse, varscan2
- FOXC2 | c.570G>A p.A190= | Silent (SNP) | VAF 44/179 reads (25%) | catalogued as rs929372985; called by muse, mutect2, varscan2
- FOXG1 | c.1107C>T p.N369= | Silent (SNP) | VAF 214/1213 reads (18%) | catalogued as rs747996412, COSV57396863; called by muse, mutect2, varscan2
- GIN1 | c.220T>C p.L74= | Silent (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- GREM2 | c.381C>T p.R127= | Silent (SNP) | VAF 85/174 reads (49%) | called by muse, mutect2, varscan2
- HHEX | c.441C>T p.D147= | Silent (SNP) | VAF 41/117 reads (35%) | called by muse, mutect2, varscan2
- HHIPL1 | c.129G>A p.S43= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- HSPA6 | c.576G>A p.A192= | Silent (SNP) | VAF 364/656 reads (55%) | catalogued as rs528647804; called by mutect2, varscan2
- JPH2 | c.1137C>T p.I379= | Silent (SNP) | VAF 134/693 reads (19%) | catalogued as rs143158930, COSV100881587; ClinVar: likely benign; called by mutect2, varscan2
- KIF1B | c.4185C>T p.I1395= (on ENST00000377086 / NM_001365952.1; = p.I1349= on NM_015074.3) | Silent (SNP) | VAF 158/337 reads (47%) | called by muse, varscan2
- MAGEC1 | c.1059T>C p.I353= | Silent (SNP) | VAF 176/282 reads (62%) | catalogued as rs1199562653; called by muse, mutect2, varscan2
- MAP2 | c.801C>T p.I267= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs775528286, COSV52288621; called by muse, mutect2, varscan2
- MARCHF8 | c.411G>A p.K137= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- MORC3 | c.621A>G p.A207= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.14472G>A p.T4824= | Silent (SNP) | VAF 38/285 reads (13%) | catalogued as rs751538389, COSV67457476; called by muse, mutect2, varscan2
- NCKAP5 | c.2232A>T p.P744= | Silent (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- NTNG2 | c.777G>A p.P259= | Silent (SNP) | VAF 28/324 reads (9%) | catalogued as rs889406537; called by muse, mutect2
- NWD1 | c.1986G>A p.E662= | Silent (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- OTOG | c.8268C>T p.C2756= | Silent (SNP) | VAF 102/216 reads (47%) | catalogued as rs867232792; called by muse, mutect2, varscan2
- PCDH8 | c.1215G>A p.A405= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- PDE5A | c.75G>A p.R25= | Silent (SNP) | VAF 44/176 reads (25%) | called by muse, mutect2, varscan2
- PDZD8 | c.726C>T p.F242= | Silent (SNP) | VAF 51/407 reads (13%) | called by muse, mutect2, varscan2
- PJVK | c.684A>T p.S228= | Silent (SNP) | VAF 64/209 reads (31%) | called by muse, mutect2, varscan2
- RASAL3 | c.2250C>A p.L750= | Silent (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- ROBO1 | c.1197A>G p.P399= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs769738829; called by muse, mutect2, varscan2
- RYR2 | c.8253T>A p.S2751= | Silent (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- SEMA4D | c.1560C>T p.C520= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as rs750786435; called by muse, mutect2, varscan2
- SFMBT2 | c.2193C>T p.T731= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs749799350, COSV62808687; called by muse, mutect2, varscan2
- SIGLEC14 | c.972G>A p.P324= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as rs755305403, COSV99707354; called by muse, mutect2, varscan2
- SOX8 | c.807C>A p.L269= | Silent (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- STARD8 | c.2859G>A p.S953= | Silent (SNP) | VAF 137/224 reads (61%) | catalogued as rs760528533; called by muse, mutect2, varscan2
- STRADA | c.1110C>T p.A370= (on ENST00000336174 / NM_001363786.1; = p.A333= on NM_001003786.3) | Silent (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2, varscan2
- SUPT20H | c.195G>A p.E65= (on ENST00000350612 / NM_001014286.3; = p.E66= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/238 reads (5%) | called by muse, mutect2
- TBX10 | c.957G>A p.P319= | Silent (SNP) | VAF 44/412 reads (11%) | catalogued as rs201107050, COSV56875720; called by muse, mutect2, varscan2
- THADA | c.5280T>C p.N1760= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1225931400; called by muse, mutect2, varscan2
- TOGARAM2 | c.1386G>A p.T462= | Silent (SNP) | VAF 80/313 reads (26%) | catalogued as rs527747733, COSV65423208; called by muse, mutect2, varscan2
- ZNF585A | c.741T>C p.C247= (on ENST00000292841 / NM_001288800.2; = p.C192= on NM_152655.3) | Silent (SNP) | VAF 99/321 reads (31%) | called by muse, mutect2, varscan2
- ZNF668 | c.1227G>A p.K409= | Silent (SNP) | VAF 69/321 reads (21%) | called by muse, mutect2, varscan2
- ZNF680 | c.1443G>A p.K481= | Silent (SNP) | VAF 39/215 reads (18%) | called by muse, mutect2, varscan2
- AC002511.3 | n.214G>A | RNA (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- AC007907.1 | n.197C>A | RNA (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- APPL1 | c.1695+17T>A | Intron (SNP) | VAF 45/120 reads (38%) | catalogued as COSV55701700; called by muse, mutect2, varscan2
- ARHGAP26 | c.1538+162A>G | Intron (SNP) | VAF 52/154 reads (34%) | catalogued as rs767868471; called by muse, mutect2, varscan2
- ATP2B1 | c.3351+442C>T | Intron (SNP) | VAF 13/154 reads (8%) | called by muse, mutect2
- AURKA | c.*49G>C | 3'UTR (SNP) | VAF 30/620 reads (5%) | called by muse, mutect2
- BNC2 | c.2639+4110C>T | Intron (SNP) | VAF 20/106 reads (19%) | catalogued as rs767853915; called by muse, mutect2, varscan2
- C18orf54 | c.*10T>C | 3'UTR (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- CDK7 | c.67-28C>G | Intron (SNP) | VAF 30/96 reads (31%) | catalogued as rs970753966; called by muse, mutect2, varscan2
- CELP | chr9:133086273 C>T | 3'Flank (SNP) | VAF 148/399 reads (37%) | catalogued as rs532542696; called by muse, mutect2, varscan2
- COG6 | c.-42T>G | 5'UTR (SNP) | VAF 205/389 reads (53%) | called by muse, mutect2, varscan2
- COL6A2 | c.2461+2696C>T | Intron (SNP) | VAF 110/474 reads (23%) | catalogued as rs534856775, COSV56008091; called by muse, mutect2, varscan2
- CT47B1 | c.*13T>A | 3'UTR (SNP) | VAF 45/79 reads (57%) | catalogued as COSV64891207; called by muse, mutect2, varscan2
- DCHS2 | n.8552G>A | RNA (SNP) | VAF 38/182 reads (21%) | catalogued as rs368291883; called by muse, mutect2, varscan2
- DYRK1B | c.-32G>T | 5'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- DZANK1 | chr20:18380922 C>T | 3'Flank (SNP) | VAF 20/158 reads (13%) | called by muse, mutect2, varscan2
- FAM90A27P | n.1119C>T | RNA (SNP) | VAF 38/176 reads (22%) | called by muse, mutect2, varscan2
- FOXL2NB | c.221-310G>A | Intron (SNP) | VAF 82/288 reads (28%) | called by muse, mutect2, varscan2
- GFRA2 | c.41-219A>G | Intron (SNP) | VAF 22/199 reads (11%) | called by muse, mutect2, varscan2
- GTF2IRD2 | c.238+98C>T | Intron (SNP) | VAF 32/245 reads (13%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85565G>T | Intron (SNP) | VAF 97/423 reads (23%) | catalogued as COSV72275514, COSV72283316; called by muse, mutect2, varscan2
- NUP88 | c.1835+12A>G | Intron (SNP) | VAF 74/157 reads (47%) | called by muse, mutect2, varscan2
- OR4C4P | n.285G>T | RNA (SNP) | VAF 14/84 reads (17%) | catalogued as rs1275371030; called by mutect2, varscan2
- OSBPL2 | chr20:62233043 A>G | 5'Flank (SNP) | VAF 50/545 reads (9%) | called by muse, mutect2
- POLR2J3 | c.-8G>C | 5'UTR (SNP) | VAF 49/261 reads (19%) | called by muse, varscan2
- PSG6 | c.706+123G>T | Intron (SNP) | VAF 8/205 reads (4%) | called by muse, mutect2
- REXO2 | c.231+1023G>C | Intron (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- SLC40A1 | c.-62C>A | 5'UTR (SNP) | VAF 75/244 reads (31%) | called by muse, mutect2
- SPATA31C1 | n.2170C>G | RNA (SNP) | VAF 56/601 reads (9%) | called by muse, mutect2
- TSPAN12 | c.-42G>A | 5'UTR (SNP) | VAF 59/296 reads (20%) | called by muse, mutect2, varscan2
- TSPYL2 | c.1918+19_1918+20dup | Intron (INS) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- ZSCAN18 | c.49+18G>A | Intron (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
